Somatic mutation profile of tumor specimen TCGA-XE-AANR-01A (aliquot TCGA-XE-AANR-01A-11D-A435-10) from TCGA case TCGA-XE-AANR, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 24.0 years (8,761 days).
Specimen TCGA-XE-AANR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 307cfd0c-1cc2-41da-81b4-e6a807029f14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AANR-10A (Blood Derived Normal), aliquot TCGA-XE-AANR-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f2d50ab-11d7-4291-883d-2a267bd73bc9

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 34/56 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.1048C>A p.R350S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV100972442; called by muse, mutect2, varscan2
- CASC3 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1481055836; called by muse, mutect2, varscan2
- GRIA1 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370642711; called by muse, mutect2, varscan2
- PADI3 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146338253, COSV64935328; called by muse, mutect2, varscan2
- TMEM259 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746881428; called by muse, mutect2, varscan2
- FAR1 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- MEGF8 | c.7013A>T p.N2338I (on ENST00000251268 / NM_001271938.2; = p.N2271I on NM_001410.3) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- STRIP1 | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UBR1 | c.1705A>G p.K569E | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR22 | c.885G>A p.R295= | Silent (SNP) | VAF 57/285 reads (20%) | catalogued as rs776396614, COSV51753698; called by muse, mutect2, varscan2
- NBAS | c.2733C>T p.D911= | Silent (SNP) | VAF 56/249 reads (22%) | called by muse, mutect2, varscan2
- ALG11 | c.44+14C>T | Intron (SNP) | VAF 18/66 reads (27%) | catalogued as rs755614049; called by muse, mutect2, varscan2
- ITGA6 | c.388-43G>T | Intron (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
